Gene-level copy-number profile of tumor specimen TARGET-10-PARNEH-09A from TARGET case TARGET-10-PARNEH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,463 days).
Specimen TARGET-10-PARNEH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.fa1419f9-11ae-5d51-8592-b51ba1ec1484.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARNEH-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate.
https://portal.gdc.cancer.gov/files/49ec308a-988b-4557-8698-e47197f8602f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,475; copy number 1: 892; copy number 2: 54,389; copy number 3: 13; copy number 4: 2,480; copy number 5: 2; copy number 6: 1; copy number 20: 11.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr3:157,543,246–157,677,749, 2 genes (within-gene range 0–2): SLC66A1L, AC084212.1.
- chr7:38,256,337–38,300,322, 8 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,560,423–142,793,368, 36 genes: TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,695,176–23,438,700, 23 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr14:22,096,032–22,482,959, 28 genes (within-gene range 0–2): TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr18:1,927,727–1,929,094, 1 gene: AIDAP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:20,377,331–20,377,401, 1 gene, copy number 6: AC004130.1.
- chr9:130,713,016–130,887,675, 1 gene, copy number 20 (within-gene range 2–20): ABL1.
- chr9:130,892,707–131,234,663, 10 genes, copy number 20 (within-gene range 1–20): QRFP, FIBCD1, AL161733.1, LAMC3, AL583807.1, AIF1L, NUP214, RNU6-881P, AL157938.2, AL157938.3.
- chr13:19,026,001–19,032,626, 2 genes, copy number 5 (within-gene range 2–5): GTF2IP3, AL137001.1.

Autosomal genes at a single copy (total copy number 1): 892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
